Somatic mutation profile of tumor specimen 0DRY7V from CCDI case PBCGHR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 6.1 years (2,234 days).
Specimen 0DRY7V: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68cb321f-534a-45cc-8b13-cae41444ce3b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRY85 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02aa7f59-4ec6-4e56-b564-795426b28b37

The open-access MAF lists 52 somatic variants for this specimen: 38 protein-altering or splice-affecting, 8 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 8, 5'UTR 3, Intron 3, Splice Site 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPK1 | c.532A>G p.T178A | Missense Mutation (SNP) | VAF 153/476 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs1352020277; called by muse, mutect2, varscan2
- ATP13A4 | c.946G>C p.E316Q | Missense Mutation (SNP) | VAF 18/416 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99795341; called by muse, mutect2
- CASP4 | c.568G>C p.A190P | Missense Mutation (SNP) | VAF 144/460 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.313); catalogued as COSV67744372; called by muse, mutect2, varscan2
- CDH24 | c.943G>T p.G315C | Missense Mutation (SNP) | VAF 102/544 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99400509; called by muse, mutect2, varscan2
- CEP170 | c.4687G>C p.D1563H | Missense Mutation (SNP) | VAF 140/628 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100317089; called by muse, mutect2, varscan2
- GCNT3 | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 103/605 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV101251888; called by muse, mutect2, varscan2
- MYT1L | c.2484G>C p.R828S | Missense Mutation (SNP) | VAF 142/409 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV67720834; called by muse, mutect2, varscan2
- NCAPG2 | c.2144C>T p.S715F | Missense Mutation (SNP) | VAF 250/1283 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.938); catalogued as rs1453744532; called by muse, mutect2, varscan2
- OR5M8 | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 53/787 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs777698910, COSV59118465; called by muse, mutect2
- RNF25 | c.1043G>A p.R348Q | Missense Mutation (SNP) | VAF 133/524 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs776331507, COSV55306048; called by muse, mutect2, varscan2
- STEAP1B | c.374G>C p.G125A | Missense Mutation (SNP) | VAF 53/1614 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1280576057; called by muse, mutect2
- TRIML2 | c.928G>A p.V310M | Missense Mutation (SNP) | VAF 140/322 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753317409, COSV58718940; called by muse, mutect2, varscan2
- UBQLN3 | c.1922C>T p.T641M | Missense Mutation (SNP) | VAF 226/691 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs531602870, COSV61163520; called by muse, mutect2, varscan2
- ZNF681 | c.488G>A p.R163K | Missense Mutation (SNP) | VAF 71/501 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.236); catalogued as rs1293024139, COSV68075379; called by muse, mutect2, varscan2
- ZNF845 | c.1084A>G p.K362E | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs1239350099, COSV72004794; called by muse, mutect2
- AHNAK2 | c.5617A>T p.I1873F | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); called by muse, mutect2
- ATF7IP | c.1645+1G>C p.X549_splice | Splice Site (SNP) | VAF 22/551 reads (4%) | called by muse, mutect2
- CNTRL | c.64C>G p.P22A | Missense Mutation (SNP) | VAF 411/1427 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- COL14A1 | c.4363G>C p.E1455Q | Missense Mutation (SNP) | VAF 69/1298 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- EEF2 | c.453C>G p.I151M | Missense Mutation (SNP) | VAF 20/689 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.305); called by muse, mutect2
- GCNT7 | c.163G>C p.G55R | Missense Mutation (SNP) | VAF 235/922 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 26/842 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- IKZF4 | c.469G>A p.G157S | Missense Mutation (SNP) | VAF 34/1114 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- IQGAP1 | c.4573G>C p.D1525H | Missense Mutation (SNP) | VAF 167/742 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ITGA4 | c.362A>G p.E121G | Missense Mutation (SNP) | VAF 129/456 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- KIAA1191 | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 196/824 reads (24%) | called by muse, mutect2, varscan2
- MTSS1 | c.1571C>T p.S524L | Missense Mutation (SNP) | VAF 128/751 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- MUC17 | c.9382A>T p.T3128S | Missense Mutation (SNP) | VAF 165/1082 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- NADSYN1 | c.1076G>T p.G359V | Missense Mutation (SNP) | VAF 104/313 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOXA1 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 76/562 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- PA2G4 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 148/865 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- RGPD3 | c.37G>T p.A13S | Missense Mutation (SNP) | VAF 89/405 reads (22%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.84); called by muse, varscan2
- SFXN5 | c.946-1G>C p.X316_splice | Splice Site (SNP) | VAF 218/661 reads (33%) | called by muse, mutect2, varscan2
- TEX15 | c.808A>G p.I270V (on ENST00000256246; = p.I653V on NM_001350162.2) | Missense Mutation (SNP) | VAF 157/719 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- UBC | c.357G>C p.L119F | Missense Mutation (SNP) | VAF 151/771 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- UBE4B | c.3221C>G p.S1074C (on ENST00000343090 / NM_001105562.3; = p.S945C on NM_006048.5) | Missense Mutation (SNP) | VAF 212/994 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- UCKL1 | c.1020C>G p.I340M | Missense Mutation (SNP) | VAF 35/548 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.398); called by muse, mutect2
- WWC1 | c.2836G>A p.D946N | Missense Mutation (SNP) | VAF 38/1072 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2
- AKT1 | c.1047C>T p.F349= | Silent (SNP) | VAF 153/596 reads (26%) | called by muse, mutect2, varscan2
- CCDC93 | c.414C>T p.I138= | Silent (SNP) | VAF 20/651 reads (3%) | called by muse, mutect2
- CCHCR1 | c.2067G>A p.Q689= | Silent (SNP) | VAF 129/545 reads (24%) | called by muse, mutect2, varscan2
- NFKBIA | c.816G>C p.L272= | Silent (SNP) | VAF 34/752 reads (5%) | called by muse, mutect2
- RGPD3 | c.36C>A p.V12= | Silent (SNP) | VAF 89/405 reads (22%) | called by muse, varscan2
- SACS | c.10434G>A p.L3478= | Silent (SNP) | VAF 52/888 reads (6%) | called by muse, mutect2
- SP8 | c.864C>T p.P288= (on ENST00000361443 / NM_198956.4; = p.P306= on NM_182700.6) | Silent (SNP) | VAF 23/364 reads (6%) | called by muse, mutect2
- ZNF76 | c.798C>T p.F266= | Silent (SNP) | VAF 77/783 reads (10%) | called by muse, mutect2, varscan2
- CTH | c.1000-26C>A | Intron (SNP) | VAF 405/846 reads (48%) | called by muse, mutect2, varscan2
- FAM167B | c.-10C>A | 5'UTR (SNP) | VAF 18/442 reads (4%) | called by muse, mutect2
- PAIP1 | c.-4G>C | 5'UTR (SNP) | VAF 29/378 reads (8%) | called by muse, mutect2
- PNPLA3 | c.-86G>C | 5'UTR (SNP) | VAF 17/92 reads (18%) | called by muse, mutect2, varscan2
- TATDN1 | c.593+49C>T | Intron (SNP) | VAF 52/267 reads (19%) | called by muse, mutect2, varscan2
- VDAC3 | c.271-68A>G | Intron (SNP) | VAF 69/120 reads (58%) | called by muse, mutect2, varscan2
